Gene-level copy-number profile of tumor specimen C3L-02125-07 from CPTAC case C3L-02125, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G3; Age at diagnosis: 68.0 years (24,837 days).
Specimen C3L-02125-07: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fd9e4f6b-5270-47ef-acf8-738f40710d2d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02125-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,249 have no estimate.
https://portal.gdc.cancer.gov/files/916b7e89-8804-4ee3-b69a-84bb6f3c19ed

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 70; copy number 2: 20,258; copy number 3: 11,698; copy number 4: 22,029; copy number 5: 1,229; copy number 6: 1,774; copy number 7: 964; copy number 8: 149; copy number 9: 12; copy number 10: 84; copy number 11: 82; copy number 12: 2; copy number 14: 9.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–2): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr8:12,115,767–12,177,550, 6 genes (within-gene range 0–1): FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr22:38,952,741–38,992,804, 2 genes (within-gene range 0–4): APOBEC3A, APOBEC3B.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 189 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:155,749,662–156,192,203, 22 genes, copy number 10 (within-gene range 4–10): GON4L, AL139128.1, SYT11, RIT1, KHDC4, SNORA80E, SCARNA4, SCARNA4, RXFP4, ARHGEF2, MIR6738, AL355388.1, ARHGEF2-AS1, AL355388.2, SSR2, UBQLN4, LAMTOR2, RAB25, MEX3A, LMNA, SEMA4A, AL135927.1.
- chr3:193,740,471–193,766,003, 2 genes, copy number 12: RN7SL447P, AC069421.1.
- chr12:53,064,316–53,345,315, 20 genes, copy number 9–14 (within-gene range 3–14): SPRYD3, IGFBP6, SOAT2, VTI1BP3, RNU6-333P, HIGD1AP1, EIF4A1P4, CSAD, AC073573.1, ZNF740, ITGB7, RARG, MFSD5, ESPL1, PFDN5, AC073611.1, MYG1-AS1, MYG1, AAAS, SP7.
- chr14:104,450,979–105,181,323, 35 genes, copy number 11: CEND1P1, TMEM179, C14orf180, BX927359.1, AL583722.2, LINC02280, MIR4710, INF2, AL583722.3, ADSS1, SIVA1, AL583722.1, AKT1, ZBTB42, AL590326.1, LINC00638, RPS26P49, RPS2P4, AL583810.2, AL583810.1, CEP170B, AL583810.3, PLD4, AHNAK2, CLBA1, CDCA4, GPR132, LINC02298, AL512356.4, AL512356.3, AL512356.2, JAG2, MIR6765, AL512356.1, NUDT14.
- chr15:89,895,006–90,645,345, 34 genes, copy number 10 (within-gene range 2–10): ARPIN, RNU7-111P, AC027176.1, AC027176.3, ZNF710, MIR3174, AC087284.1, ZNF710-AS1, U7, IDH2, IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P, GABARAPL3, GABARAPL3, ZNF774, NDUFA3P4, IQGAP1, AC018946.1, CRTC3.
- chr16:46,469,341–46,569,097, 1 gene, copy number 9 (within-gene range 5–9): ANKRD26P1.
- chr17:39,461,486–40,195,656, 37 genes, copy number 11: CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867.
- chr17:44,846,353–45,269,824, 28 genes, copy number 10 (within-gene range 7–10): HIGD1B, EFTUD2, RN7SL405P, CCDC103, FAM187A, GFAP, KIF18B, MIR6783, AC015936.1, NMT1, C1QL1, AC015936.2, DCAKD, Y_RNA, PLCD3, MIR6784, ACBD4, AC142472.1, HEXIM1, AC138150.1, HEXIM2, AC138150.2, AC008105.3, FMNL1, AC008105.1, AC008105.2, MAP3K14-AS1, SPATA32.
- chr17:73,163,035–73,312,005, 10 genes, copy number 11: POLR3KP2, AC097641.1, SSTR2, COG1, AC097641.2, FAM104A, C17orf80, AC087301.1, CPSF4L, CDC42EP4.

Autosomal genes at a single copy (total copy number 1): 70. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
